Somatic mutation profile of tumor specimen HCM-WCMC-0502-C15-01A (aliquot HCM-WCMC-0502-C15-01A-10D-A83U-36) from HCMI case HCM-WCMC-0502-C15, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; AJCC pathologic stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 42.9 years (15,658 days).
Specimen HCM-WCMC-0502-C15-01A: Sample type: Slides; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ddf61c8d-53c7-439c-bcfd-844d2ef5e185.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-WCMC-0502-C15-10A (Blood Derived Normal), aliquot HCM-WCMC-0502-C15-10A-01D-A83U-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/22d23efd-5611-49d0-917c-eea300ac41d3

The open-access MAF lists 69 somatic variants for this specimen: 59 protein-altering or splice-affecting, 9 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 51, Silent 9, Nonsense Mutation 6, In Frame Del 1, Intron 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.83_100del p.V28_E33del | In Frame Del (DEL) | VAF 124/720 reads (17%) | hotspot (GDC flag); called by mutect2, varscan2
- SMAD4 | c.1082G>A p.R361H | Missense Mutation (SNP) | VAF 73/568 reads (13%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs377767347, CM004254, CM100519, COSV61684056, COSV61686014, COSV61689167; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 137/598 reads (23%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: not provided / uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TTN | c.50737C>T p.R16913* (on ENST00000591111; = p.R9489* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 71/696 reads (10%) | catalogued as rs1483931960, COSV59888643; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ACTC1 | c.554G>A p.R185Q | Missense Mutation (SNP) | VAF 99/489 reads (20%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.538); catalogued as rs866147243; called by muse, mutect2, varscan2
- ADGRD1 | c.2609A>G p.D870G | Missense Mutation (SNP) | VAF 24/530 reads (5%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.996); catalogued as rs751799117, COSV55452829; called by muse, mutect2
- CIC | c.3613C>T p.R1205W | Missense Mutation (SNP) | VAF 46/715 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.898); catalogued as rs540906276; called by muse, mutect2
- CKAP5 | c.697C>T p.R233C | Missense Mutation (SNP) | VAF 21/725 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1326516110, COSV56367217; called by muse, mutect2
- CLC | c.385del p.D129Ifs*4 | Frame Shift Del (DEL) | VAF 65/314 reads (21%) | catalogued as COSV55686288; called by mutect2, varscan2
- DAAM1 | c.1250A>T p.D417V | Missense Mutation (SNP) | VAF 28/796 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.609); catalogued as COSV62840209; called by muse, mutect2
- DNAH3 | c.1225G>T p.A409S | Missense Mutation (SNP) | VAF 31/300 reads (10%) | SIFT tolerated (0.28); PolyPhen benign (0.204); catalogued as COSV54511759, COSV99770890; called by muse, mutect2, varscan2
- FSHR | c.924G>T p.R308S | Missense Mutation (SNP) | VAF 24/387 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV58629737; called by muse, mutect2
- HAS1 | c.983A>C p.K328T | Missense Mutation (SNP) | VAF 19/577 reads (3%) | SIFT tolerated (0.59); PolyPhen benign (0.012); catalogued as COSV99708332; called by muse, mutect2
- MINPP1 | c.1297C>T p.R433* | Nonsense Mutation (SNP) | VAF 189/713 reads (27%) | catalogued as rs1339940985, COSV64355228; called by muse, mutect2, varscan2
- OR14K1 | c.107C>T p.A36V | Missense Mutation (SNP) | VAF 32/512 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.617); catalogued as COSV99314942; called by muse, mutect2
- PCDHA1 | c.1445C>T p.A482V | Missense Mutation (SNP) | VAF 72/346 reads (21%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.052); catalogued as rs782599305, COSV65373425; called by muse, mutect2, varscan2
- PIK3CG | c.529C>T p.R177C | Missense Mutation (SNP) | VAF 79/829 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100783114, COSV63245916; called by muse, mutect2, varscan2
- PROX2 | c.685G>T p.E229* | Nonsense Mutation (SNP) | VAF 44/565 reads (8%) | catalogued as rs1343036813; called by muse, mutect2
- PTPRD | c.5402G>A p.R1801K | Missense Mutation (SNP) | VAF 20/619 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as COSV61985617; called by muse, mutect2
- RPL3L | c.811C>A p.Q271K | Missense Mutation (SNP) | VAF 62/501 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV51906404; called by muse, mutect2, varscan2
- SETD5 | c.2705A>G p.N902S | Missense Mutation (SNP) | VAF 41/472 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.956); catalogued as rs375109664; called by muse, mutect2
- SLC22A14 | c.1333C>T p.L445F | Missense Mutation (SNP) | VAF 58/443 reads (13%) | SIFT tolerated (0.61); PolyPhen benign (0.029); catalogued as rs767352284; called by muse, mutect2, varscan2
- TGIF2LX | c.434A>C p.K145T | Missense Mutation (SNP) | VAF 29/585 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.009); catalogued as COSV52213774, COSV52213806; called by muse, mutect2
- TMEM132C | c.2852A>C p.K951T | Missense Mutation (SNP) | VAF 28/548 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV59421132; called by muse, mutect2
- UCMA | c.43G>A p.V15M | Missense Mutation (SNP) | VAF 76/425 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.006); catalogued as rs372826471; called by muse, mutect2, varscan2
- WDR87 | c.5911G>A p.A1971T | Missense Mutation (SNP) | VAF 21/461 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.169); catalogued as COSV58200582; called by muse, mutect2
- ZNF423 | c.272C>A p.T91K (on ENST00000563137 / NM_001379286.1; = p.T83K on NM_015069.4) | Missense Mutation (SNP) | VAF 43/558 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.931); catalogued as COSV52181840; called by muse, mutect2
- ACSS3 | c.694G>A p.V232I | Missense Mutation (SNP) | VAF 52/908 reads (6%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.994); called by muse, mutect2
- AGBL1 | c.2677A>C p.S893R | Missense Mutation (SNP) | VAF 23/376 reads (6%) | SIFT tolerated (0.24); PolyPhen benign (0.012); called by muse, mutect2
- B3GALT1 | c.820A>G p.K274E | Missense Mutation (SNP) | VAF 50/692 reads (7%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.615); called by muse, mutect2
- BSN | c.8064C>G p.I2688M | Missense Mutation (SNP) | VAF 49/438 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- C8orf34 | c.124G>T p.A42S | Missense Mutation (SNP) | VAF 39/916 reads (4%) | SIFT tolerated, low confidence (0.31); called by muse, mutect2
- CAPN10 | c.322T>A p.S108T | Missense Mutation (SNP) | VAF 18/556 reads (3%) | SIFT tolerated (0.39); PolyPhen benign (0.21); called by muse, mutect2
- CCM2 | c.443A>C p.D148A | Missense Mutation (SNP) | VAF 19/601 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.651); called by muse, mutect2
- CDCP1 | c.1048A>T p.S350C | Missense Mutation (SNP) | VAF 22/552 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- CFAP69 | c.1655A>G p.K552R | Missense Mutation (SNP) | VAF 10/350 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- CFAP69 | c.1656G>T p.K552N | Missense Mutation (SNP) | VAF 11/340 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- FOXD3 | c.1232G>C p.S411T | Missense Mutation (SNP) | VAF 80/622 reads (13%) | SIFT tolerated, low confidence (0.76); PolyPhen benign (0); called by muse, mutect2
- HIVEP3 | c.577A>G p.I193V | Missense Mutation (SNP) | VAF 90/633 reads (14%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.651); called by muse, mutect2, varscan2
- KEAP1 | c.269C>G p.A90G | Missense Mutation (SNP) | VAF 34/914 reads (4%) | SIFT tolerated (0.25); PolyPhen benign (0.131); called by muse, mutect2
- LAMC2 | c.2281G>A p.A761T | Missense Mutation (SNP) | VAF 60/550 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); called by muse, mutect2, varscan2
- MCEMP1 | c.65A>G p.K22R | Missense Mutation (SNP) | VAF 16/539 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.64); called by muse, mutect2
- NELL1 | c.1228T>C p.W410R | Missense Mutation (SNP) | VAF 125/615 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.537); called by muse, mutect2, varscan2
- NR5A1 | c.47G>T p.C16F | Missense Mutation (SNP) | VAF 89/434 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NYAP2 | c.1694A>C p.H565P | Missense Mutation (SNP) | VAF 87/550 reads (16%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- P2RX2 | c.1082G>T p.G361V | Missense Mutation (SNP) | VAF 65/562 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- P4HA3 | c.773C>A p.P258Q | Missense Mutation (SNP) | VAF 15/287 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- PANX1 | c.496A>T p.R166* | Nonsense Mutation (SNP) | VAF 38/700 reads (5%) | called by muse, mutect2
- PPM1F | c.737C>G p.A246G | Missense Mutation (SNP) | VAF 12/291 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); called by muse, mutect2
- PPP2R1A | c.724G>T p.A242S | Missense Mutation (SNP) | VAF 235/1062 reads (22%) | SIFT tolerated (0.64); PolyPhen benign (0); called by muse, mutect2, varscan2
- STARD8 | c.3038C>A p.T1013N | Missense Mutation (SNP) | VAF 64/273 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- STK11IP | c.1133A>G p.K378R | Missense Mutation (SNP) | VAF 12/274 reads (4%) | SIFT tolerated (0.2); PolyPhen benign (0.275); called by muse, mutect2
- STK11IP | c.1134G>T p.K378N | Missense Mutation (SNP) | VAF 12/265 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2
- STON1 | c.1619A>C p.Y540S | Missense Mutation (SNP) | VAF 64/518 reads (12%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.862); called by muse, mutect2, varscan2
- TNFRSF8 | c.184C>A p.P62T | Missense Mutation (SNP) | VAF 30/480 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.142); called by muse, mutect2
- TTN | c.69346A>T p.K23116* (on ENST00000591111; = p.K15692* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 72/430 reads (17%) | called by muse, mutect2, varscan2
- UBC | c.2008C>T p.Q670* | Nonsense Mutation (SNP) | VAF 134/702 reads (19%) | called by muse, varscan2
- XIRP2 | c.2500A>T p.I834F (on ENST00000628543; = p.I1009F on NM_152381.6) | Missense Mutation (SNP) | VAF 72/800 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2
- ZNF829 | c.946A>G p.R316G | Missense Mutation (SNP) | VAF 35/603 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.517); called by muse, mutect2
- CADM2 | c.519A>G p.K173= (on ENST00000407528 / NM_001167674.2; = p.K175= on NM_153184.4) | Silent (SNP) | VAF 52/516 reads (10%) | called by muse, mutect2, varscan2
- DEUP1 | c.24G>A p.T8= | Silent (SNP) | VAF 42/461 reads (9%) | catalogued as rs752444785, COSV53209745; called by muse, mutect2
- GABRQ | c.513G>C p.V171= | Silent (SNP) | VAF 62/228 reads (27%) | catalogued as COSV64783957; called by muse, mutect2, varscan2
- HCN4 | c.2652C>A p.P884= | Silent (SNP) | VAF 174/632 reads (28%) | called by muse, mutect2, varscan2
- HNF1B | c.441G>A p.Q147= | Silent (SNP) | VAF 74/1142 reads (6%) | called by muse, mutect2
- MROH1 | c.3403C>T p.L1135= | Silent (SNP) | VAF 77/560 reads (14%) | called by muse, mutect2, varscan2
- NR4A1 | c.894C>T p.N298= | Silent (SNP) | VAF 101/394 reads (26%) | catalogued as rs768092406, COSV54482935; called by muse, mutect2, varscan2
- NXPH1 | c.157T>C p.L53= | Silent (SNP) | VAF 48/734 reads (7%) | catalogued as COSV101339701, COSV68318636; called by muse, mutect2
- RABGEF1 | c.1509A>T p.A503= (on ENST00000439720 / NM_001287061.2; = p.A490= on NM_014504.3 and 29 other RefSeq transcripts) | Silent (SNP) | VAF 28/455 reads (6%) | called by muse, mutect2
- RPS29 | c.162+40G>A | Intron (SNP) | VAF 147/693 reads (21%) | called by muse, mutect2, varscan2
